Somatic mutation profile of tumor specimen MP2PRT-PANVCH-TBP1-A (aliquot MP2PRT-PANVCH-TBP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANVCH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (654 days).
Specimen MP2PRT-PANVCH-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac451e30-523b-4a38-8df2-89e646636d1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANVCH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANVCH-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80bf8b3c-7f35-4066-bafa-2f1405d39e53

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO5 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100201651; called by muse, mutect2, varscan2
- MARCO | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 115/390 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs766628118; called by muse, mutect2, varscan2
- C2orf16 | c.2291G>A p.R764K | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- FZD1 | c.1599dup p.M534Hfs*73 | Frame Shift Ins (INS) | VAF 74/365 reads (20%) | called by mutect2, pindel, varscan2
- SUPT6H | c.3670C>A p.Q1224K | Missense Mutation (SNP) | VAF 72/318 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.057); called by muse, varscan2
- WDR17 | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- FST | c.282G>A p.T94= | Silent (SNP) | VAF 61/216 reads (28%) | catalogued as rs1400918690; called by muse, mutect2, varscan2
- SCARA5 | c.621C>T p.D207= | Silent (SNP) | VAF 170/628 reads (27%) | catalogued as rs1287341017; called by muse, mutect2, varscan2
